Surgical pathology report (de-identified scan), TCGA case TCGA-AG-3608, project TCGA-READ (Rectum Adenocarcinoma), tissue source site Indivumed, specimen TCGA-AG-3608-01A (Primary Tumor).

Diagnosis:

Resection material from colon (sigmoid/rectum) with tumor-free oral, aboral and perirectal resection margins, with non-inflamed diverticula, with three tubular adenomas of the colon mucosa with severe dysplasia in parts (synonym: high-grade intraepithelial neoplasia) and with inclusion of a moderately differentiated adenocarcinoma or rectal carcinoma with infiltration of the perimuscular fatty tissue and without regional lymph node metastases (G2, pT3 L0, V0, R0 pN0 0/16).

Source: NCI Genomic Data Commons file 6ff840cd-0647-404e-b4f3-2ed95d6e72d1 (TCGA-AG-3608.EEEE5EA2-929C-4837-8FAB-30049D5DA028.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).